Somatic mutation profile of tumor specimen TCGA-58-8390-01A (aliquot TCGA-58-8390-01A-11D-2323-08) from TCGA case TCGA-58-8390, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.7 years (25,827 days).
Specimen TCGA-58-8390-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0a1a943-466f-4959-930b-78e6a485aea5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-58-8390-10A (Blood Derived Normal), aliquot TCGA-58-8390-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e07df399-4c98-42ef-bf89-d68b9367ad20

The open-access MAF lists 448 somatic variants for this specimen: 328 protein-altering or splice-affecting, 105 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 282, Silent 105, Nonsense Mutation 19, Splice Site 12, Frame Shift Del 9, Intron 4, Splice Region 4, 5'Flank 3, RNA 3, 3'Flank 3, Frame Shift Ins 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CB | c.3200A>T p.D1067V | Missense Mutation (SNP) | VAF 9/242 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56683107, COSV56689255; called by muse, mutect2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 19/26 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- AAMP | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1437494151; called by muse, mutect2, varscan2
- ABCA13 | c.10882A>G p.S3628G | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV71291361; called by muse, mutect2, varscan2
- ACOT7 | c.325C>T p.R109C (on ENST00000377855 / NM_181864.3; = p.R99C on NM_007274.4) | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as rs201654646, COSV64112946; called by muse, mutect2, varscan2
- ACTL6B | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as rs1293837515, COSV50519818; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4883C>T p.A1628V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV65885867; called by muse, mutect2
- ADCY7 | c.1436G>T p.R479L | Missense Mutation (SNP) | VAF 39/51 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as COSV99576023; called by muse, mutect2, varscan2
- ANK1 | c.3145A>G p.K1049E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs1304996996; called by muse, mutect2, varscan2
- ARL13B | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 111/193 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV57397563; called by muse, mutect2, varscan2
- ATP1A3 | c.1300G>T p.A434S (on ENST00000545399 / NM_001256214.2; = p.A421S on NM_152296.5) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs782154735; called by muse, mutect2, varscan2
- BACH2 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.054); catalogued as COSV57589318; called by muse, mutect2, varscan2
- BRCA2 | c.7195A>G p.T2399A | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.102); catalogued as rs80358948, COSV66456594; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.4759G>T p.G1587* | Nonsense Mutation (SNP) | VAF 29/34 reads (85%) | catalogued as COSV100955513; called by muse, mutect2, varscan2
- CC2D2A | c.2684A>T p.Q895L | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as rs1268364329; called by muse, mutect2, varscan2
- CDHR1 | c.1612G>C p.A538P | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as COSV60565497; called by muse, mutect2, varscan2
- CHKB | c.919G>T p.E307* | Nonsense Mutation (SNP) | VAF 55/172 reads (32%) | catalogued as COSV56419787; called by muse, mutect2, varscan2
- CHRNB3 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51494964; called by muse, mutect2, varscan2
- CLRN1 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV58996675; called by muse, mutect2, varscan2
- COL4A2 | c.5095C>G p.R1699G | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV100847466; called by muse, mutect2, varscan2
- CPLX4 | c.340C>T p.Q114* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as rs965292917, COSV55315027; called by muse, mutect2, varscan2
- CSMD3 | c.3583G>T p.G1195W (on ENST00000297405 / NM_001363185.1; = p.G1091W on NM_052900.3) | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52231204; called by muse, mutect2, varscan2
- CSMD3 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV52172035; called by muse, mutect2, varscan2
- CYLC1 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs1480711790; called by muse, mutect2, varscan2
- CYLD | c.2305del p.I769Ffs*7 | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | catalogued as CM103649, COSV61098007; called by mutect2, varscan2
- DAO | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs372560295; called by muse, mutect2, varscan2
- DCDC1 | c.4448A>T p.E1483V (on ENST00000597505 / NM_001367979.1; = p.E590V on NM_020869.3) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV100338081; called by muse, mutect2, varscan2
- DNAH10 | c.9451G>T p.A3151S (on ENST00000409039; = p.A3090S on NM_207437.3) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV68994162; called by muse, mutect2, varscan2
- DNAH8 | c.11982G>T p.W3994C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59479471; called by muse, mutect2, varscan2
- DNMBP | c.3716C>T p.P1239L | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs761437921; called by muse, varscan2
- DNMT1 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 88/120 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV61576675; called by muse, mutect2, varscan2
- DSCAM | c.5746C>A p.P1916T | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV68027041; called by muse, mutect2, varscan2
- EFCAB3 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV59500745; called by muse, mutect2, varscan2
- ENPP2 | c.790G>C p.A264P | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99308175; called by muse, mutect2, varscan2
- ENPP7 | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60387552; called by muse, mutect2, varscan2
- EXOC4 | c.1759G>T p.V587F | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV54098479; called by muse, mutect2, varscan2
- FGFR2 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100335957, COSV60660026; called by muse, mutect2, varscan2
- FHOD1 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs762232923; called by muse, mutect2, varscan2
- FIGN | c.1115C>T p.S372L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.047); catalogued as COSV100291952; called by muse, mutect2, varscan2
- FN1 | c.2952G>T p.R984S | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.217); catalogued as COSV100118470; called by muse, mutect2, varscan2
- FSHR | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs760697660; called by muse, mutect2, varscan2
- GABRA2 | c.1127C>G p.P376R | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100733842, COSV100734631; called by muse, mutect2, varscan2
- GATA5 | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV53346943; called by muse, mutect2, varscan2
- GPATCH8 | c.3119G>T p.R1040L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs764196420; called by muse, mutect2, varscan2
- GPC6 | c.910G>T p.G304W | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100990261; called by muse, mutect2, varscan2
- GRB7 | c.1144G>T p.G382W | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100485518; called by muse, varscan2
- HGD | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52199231, COSV52199514; called by muse, mutect2, varscan2
- HIVEP1 | c.6511G>T p.E2171* | Nonsense Mutation (SNP) | VAF 60/137 reads (44%) | catalogued as COSV65102523; called by muse, mutect2, varscan2
- HMX2 | c.749C>A p.A250E | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100378723; called by muse, mutect2, varscan2
- HRH3 | c.1240C>A p.L414M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100420773; called by muse, mutect2, varscan2
- JPH3 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52474032; called by muse, mutect2, varscan2
- LPA | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 72/213 reads (34%) | catalogued as rs533200556, COSV60300564; called by muse, mutect2, varscan2
- MPP4 | c.1204A>C p.T402P | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59632266; called by muse, mutect2
- MRO | c.121C>T p.Q41* | Nonsense Mutation (SNP) | VAF 66/192 reads (34%) | catalogued as rs371333006; called by muse, mutect2
- MROH2B | c.4327G>A p.D1443N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV68182472; called by muse, mutect2, varscan2
- MROH7 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs773181857, COSV59874957; called by muse, mutect2, varscan2
- MTA2 | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.456); catalogued as rs778750208; called by muse, mutect2, varscan2
- MYH8 | c.1738T>G p.F580V | Missense Mutation (SNP) | VAF 61/89 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67966448; called by muse, mutect2, varscan2
- MYLK | c.5200G>A p.D1734N | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759881799; called by muse, mutect2, varscan2
- NCAM2 | c.2350G>T p.D784Y | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV53067931, COSV53105528; called by muse, mutect2, varscan2
- NID2 | c.2017T>A p.S673T | Missense Mutation (SNP) | VAF 55/85 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as COSV53497947; called by muse, mutect2, varscan2
- NKD1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1236278122, COSV51692294; called by muse, mutect2, varscan2
- NLRP14 | c.569C>T p.T190I | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs149141405, COSV55067798; called by muse, mutect2, varscan2
- NOTCH1 | c.5167+1G>T p.X1723_splice | Splice Site (SNP) | VAF 51/60 reads (85%) | catalogued as COSV53080636; called by muse, mutect2, varscan2
- NUP205 | c.5239G>T p.D1747Y | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1474943816; called by muse, mutect2, varscan2
- OCRL | c.2650C>G p.R884G | Missense Mutation (SNP) | VAF 119/146 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV100843431; called by muse, mutect2, varscan2
- OMP | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs370927367; called by muse, mutect2
- OPN5 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55245148; called by muse, mutect2, varscan2
- OR4M1 | c.415C>A p.R139S | Missense Mutation (SNP) | VAF 104/155 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs148303756; called by muse, mutect2, varscan2
- OR4S2 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs757624689; called by muse, mutect2, varscan2
- OR8K1 | c.415G>T p.V139L | Missense Mutation (SNP) | VAF 122/235 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs779347763, COSV54402175, COSV99039463; called by muse, mutect2, varscan2
- PCDH15 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.572); catalogued as rs1564545545, COSV100213918, COSV100214304; called by muse, mutect2, varscan2
- PCDH15 | c.211C>G p.P71A | Missense Mutation (SNP) | VAF 117/286 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.042); catalogued as COSV57364103; called by muse, mutect2, varscan2
- PIK3CG | c.1114G>T p.V372F | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV63252415; called by muse, mutect2, varscan2
- PIKFYVE | c.5434C>T p.Q1812* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as rs1244487517, COSV52242080, COSV52245055; called by muse, mutect2, varscan2
- PLEKHH2 | c.2214G>A p.P738= | Splice Region (SNP) | VAF 41/123 reads (33%) | catalogued as rs746242308, COSV56754948; called by muse, mutect2, varscan2
- PNLIPRP1 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724508; called by muse, mutect2, varscan2
- POLE3 | c.334A>C p.K112Q | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs776313444, COSV55913148; called by muse, mutect2, varscan2
- POM121L12 | c.370C>A p.L124M | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV101374811; called by muse, mutect2, varscan2
- PPRC1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1228326899, COSV53385853; called by muse, mutect2, varscan2
- PRKD1 | c.2102A>G p.N701S | Missense Mutation (SNP) | VAF 61/81 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs764301676; called by muse, mutect2, varscan2
- PYGM | c.1000-1G>C p.X334_splice | Splice Site (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99377018; called by muse, mutect2, varscan2
- QRFPR | c.1107G>C p.M369I | Missense Mutation (SNP) | VAF 81/113 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV57678068; called by muse, mutect2, varscan2
- RCBTB2 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs144657295, COSV60651248; called by muse, mutect2, varscan2
- RELN | c.4147A>G p.K1383E | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.874); catalogued as rs1429778478; called by muse, mutect2, varscan2
- RUNX2 | c.1012C>G p.R338G | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV61839008; called by muse, mutect2, varscan2
- RYR3 | c.6074G>T p.R2025L | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66786737; called by muse, mutect2, varscan2
- SAGE1 | c.1440G>T p.L480= | Splice Region (SNP) | VAF 76/91 reads (84%) | catalogued as COSV61015676; called by muse, mutect2, varscan2
- SAMD8 | c.350A>G p.H117R | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1432410164, COSV65509998; called by muse, mutect2, varscan2
- SEM1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs543465507; called by muse, mutect2, varscan2
- SEZ6L2 | c.2254A>T p.T752S (on ENST00000308713 / NM_001114099.3; = p.T682S on NM_012410.4) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.989); catalogued as rs776612384; called by muse, mutect2, varscan2
- SLC24A3 | c.1922G>A p.C641Y | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60130423; called by muse, mutect2, varscan2
- SLITRK3 | c.2786C>A p.A929D | Missense Mutation (SNP) | VAF 92/292 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV53848453; called by muse, mutect2, varscan2
- SORT1 | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs573383155, COSV56670234; called by muse, mutect2
- TGM6 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs574491323, COSV52478921, COSV52483976; called by muse, mutect2, varscan2
- THSD7B | c.380G>C p.R127P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV55714925; called by muse, mutect2, varscan2
- TLR5 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.024); catalogued as rs1240980787; called by muse, mutect2, varscan2
- TMEM144 | c.388A>G p.I130V | Missense Mutation (SNP) | VAF 66/92 reads (72%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs769750696; called by muse, mutect2, varscan2
- TMEM200A | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs780602819, COSV51655808; called by muse, mutect2, varscan2
- TRBV27 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 34/100 reads (34%) | catalogued as rs1446585163; called by muse, mutect2, varscan2
- TRIM56 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.552); catalogued as rs61758108; called by muse, mutect2
- TTN | c.1196C>A p.S399* | Nonsense Mutation (SNP) | VAF 49/117 reads (42%) | catalogued as COSV100594573; called by muse, mutect2, varscan2
- TUBA3C | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV67139540; called by muse, mutect2, varscan2
- UAP1 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 137/453 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.264); catalogued as rs758345601, COSV54848911; called by muse, mutect2, varscan2
- UNC45B | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99268721; called by muse, mutect2, varscan2
- USP40 | c.3392C>A p.P1131Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV99295970; called by muse, mutect2, varscan2
- VPS51 | c.1975C>T p.R659C | Missense Mutation (SNP) | VAF 100/259 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1197338811; called by muse, mutect2, varscan2
- ZBBX | c.2003G>C p.R668T | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV56781846; called by muse, mutect2, varscan2
- ZNF335 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs750099536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF99 | c.1165A>G p.I389V | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as rs776943563; called by muse, mutect2, varscan2
- ABAT | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ABL2 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.716); called by muse, mutect2
- ACSM3 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ACTR3B | c.57dup p.G20Wfs*7 | Frame Shift Ins (INS) | VAF 27/167 reads (16%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.3384T>A p.F1128L | Missense Mutation (SNP) | VAF 84/200 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ADRB1 | c.1049A>G p.H350R | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ALDH18A1 | c.1124G>T p.R375M | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ALDH1L2 | c.1435T>G p.L479V | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMACR | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- AMER3 | c.1669del p.A557Rfs*127 | Frame Shift Del (DEL) | VAF 9/26 reads (35%) | called by pindel, varscan2
- ANK3 | c.3629G>A p.R1210Q (on ENST00000280772 / NM_001320874.2; = p.R344Q on NM_001149.3) | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ANKRD30A | c.3808G>T p.A1270S (on ENST00000611781; = p.A1214S on NM_052997.2) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ANKS1B | c.1453G>T p.V485L | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- APBB1IP | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- APOB | c.4882G>T p.A1628S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- APOBEC3G | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.42); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ARHGAP35 | c.357A>T p.R119S | Missense Mutation (SNP) | VAF 86/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP44 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.773); called by muse, varscan2
- ASB11 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AZI2 | c.316T>G p.L106V | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C1GALT1 | c.189G>T p.M63I | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3 | c.4675G>A p.D1559N | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- CA8 | c.842G>T p.S281I | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CACYBP | c.436A>C p.K146Q | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASR | c.2939C>A p.S980Y (on ENST00000490131; = p.S1057Y on NM_000388.4) | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CCR2 | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCR6 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CD1E | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- CD300LG | c.887C>A p.T296N | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH10 | c.1634C>A p.A545D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH7 | c.1744G>T p.V582L | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- CELSR2 | c.4729G>T p.V1577L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP290 | c.6088C>A p.H2030N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.11); called by muse, mutect2
- CFAP47 | c.5155T>A p.Y1719N | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CHRNB2 | c.778T>C p.S260P | Missense Mutation (SNP) | VAF 143/238 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CILP | c.1029G>C p.W343C | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLASP1 | c.4357A>T p.I1453F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CMYA5 | c.3535G>A p.A1179T | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CNNM1 | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 53/155 reads (34%) | called by muse, mutect2, varscan2
- CNNM2 | c.81G>T p.M27I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.096); called by muse, mutect2
- COL24A1 | c.435C>G p.H145Q | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- COL4A2 | c.604G>T p.G202W | Missense Mutation (SNP) | VAF 75/94 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CREBBP | c.4896_4900del p.F1633Dfs*25 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- CRYBA2 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CRYBG1 | c.1706G>T p.R569L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTCFL | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTPS2 | c.1696A>T p.R566* | Nonsense Mutation (SNP) | VAF 50/59 reads (85%) | called by muse, mutect2, varscan2
- CTSG | c.563G>T p.G188V | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DAZ2 | c.531G>T p.Q177H | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- DCHS1 | c.3388A>G p.T1130A | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DDX47 | c.975_979del p.L327Hfs*11 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | called by mutect2, pindel, varscan2
- DDX60L | c.2220G>T p.Q740H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DEPP1 | c.445dup p.R149Kfs*6 | Frame Shift Ins (INS) | VAF 26/59 reads (44%) | called by mutect2, pindel, varscan2
- DIP2A | c.4234G>T p.D1412Y | Missense Mutation (SNP) | VAF 56/77 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DMTF1 | c.1052T>A p.I351K | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- DNAH9 | c.2797T>C p.F933L | Missense Mutation (SNP) | VAF 95/127 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DOT1L | c.3299G>T p.S1100I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- DPP4 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DPP8 | c.1060G>A p.G354R (on ENST00000341861 / NM_001320875.2; = p.G338R on NM_017743.6) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- DROSHA | c.2866G>T p.D956Y | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DST | c.19797G>T p.Q6599H (on ENST00000361203 / NM_001374722.1; = p.Q4296H on NM_015548.5) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.3166C>A p.L1056M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ENTPD2 | c.777C>A p.T259= | Splice Region (SNP) | VAF 30/35 reads (86%) | called by muse, mutect2, varscan2
- EPC1 | c.2308G>A p.A770T | Missense Mutation (SNP) | VAF 114/273 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHA7 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- EYS | c.1476G>C p.K492N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO30 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 63/151 reads (42%) | called by muse, mutect2, varscan2
- FCRL2 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- FGD4 | c.1339-1G>T p.X447_splice | Splice Site (SNP) | VAF 43/93 reads (46%) | called by muse, mutect2, varscan2
- FIGNL1 | c.1597A>T p.T533S | Missense Mutation (SNP) | VAF 84/111 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- FSCN3 | c.1087A>T p.N363Y | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- GART | c.3017G>T p.W1006L | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GCC1 | c.2132G>T p.R711M | Missense Mutation (SNP) | VAF 63/193 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLYAT | c.390A>T p.Q130H | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- GPLD1 | c.2417C>A p.T806N | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- GPR50 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 72/89 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- HECW2 | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HIVEP2 | c.6410A>T p.Y2137F | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HK2 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLF | c.196G>T p.G66W | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXD3 | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HPN | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- HR | c.707A>C p.H236P | Missense Mutation (SNP) | VAF 79/130 reads (61%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HSPG2 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HTT | c.2617G>A p.A873T | Missense Mutation (SNP) | VAF 103/211 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HYDIN | c.11084C>A p.S3695Y | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ICAM1 | c.146G>T p.S49I | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.230C>G p.T77R | Missense Mutation (SNP) | VAF 74/458 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- IL17RB | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IL1RL1 | c.1109C>A p.T370N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ING3 | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITGA9 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 61/85 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ITIH1 | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ITPRID2 | c.1949G>A p.S650N | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JUNB | c.34G>C p.D12H | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KATNA1 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.82); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KDM7A | c.1763+2T>C p.X588_splice | Splice Site (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- L1TD1 | c.1067G>C p.S356T | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LAMA2 | c.451A>T p.N151Y | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCT | c.507G>C p.W169C | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LDB2 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LGI1 | c.1284C>A p.N428K | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LMAN2L | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- LRIG3 | c.1739A>G p.Q580R | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRP2 | c.12574G>T p.V4192L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP8 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- LRRC37A2 | c.3607G>T p.E1203* | Nonsense Mutation (SNP) | VAF 73/558 reads (13%) | called by muse, mutect2, varscan2
- LRRTM4 | c.143A>T p.E48V | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MACF1 | c.19554C>G p.I6518M (on ENST00000372915; = p.I4563M on NM_012090.5) | Missense Mutation (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- MAP4K1 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MATN2 | c.961G>C p.V321L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- MGST1 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- MS4A8 | c.125A>G p.Q42R | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MSANTD1 | c.173G>T p.W58L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- MUC16 | c.29492T>A p.L9831Q | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- MUC16 | c.29383G>T p.A9795S | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MYF5 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MYH13 | c.2651T>G p.L884R | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MYOM1 | c.536C>G p.T179R | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- NBAS | c.3156del p.K1052Nfs*24 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | called by mutect2, pindel, varscan2
- NEDD9 | c.955G>T p.V319F | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NEK10 | c.1757A>T p.N586I | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NFIB | c.807-1G>A p.X269_splice | Splice Site (SNP) | VAF 47/72 reads (65%) | called by muse, mutect2, varscan2
- NLRP3 | c.98A>C p.Q33P | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NOS1 | c.2539A>G p.K847E | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NOVA1 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2
- NOVA1 | c.541A>C p.S181R | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- NPAS2 | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T12 | c.503del p.G168Vfs*36 | Frame Shift Del (DEL) | VAF 68/144 reads (47%) | called by mutect2, varscan2
- OR5AS1 | c.77C>A p.T26K | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR5B12 | c.890G>T p.S297I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- OR8H3 | c.13A>T p.R5W | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR8I2 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PAX3 | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDH11X | c.2625G>T p.K875N | Missense Mutation (SNP) | VAF 45/54 reads (83%) | SIFT tolerated (0.13); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PCDHA6 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 61/90 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA4 | c.637G>T p.V213L | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PCDHGC4 | c.2053G>A p.G685R | Missense Mutation (SNP) | VAF 36/53 reads (68%) | SIFT tolerated (0.37); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PCGF5 | c.294G>C p.W98C | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PCSK6 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE1B | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDE3B | c.2369A>G p.K790R | Missense Mutation (SNP) | VAF 85/115 reads (74%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PDIA6 | c.428del p.S143Tfs*20 | Frame Shift Del (DEL) | VAF 21/64 reads (33%) | called by mutect2, pindel*
- PGRMC1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 61/70 reads (87%) | called by muse, mutect2, varscan2
- PIGN | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PITPNM1 | c.415+1G>A p.X139_splice | Splice Site (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- PLA2R1 | c.3710-2A>G p.X1237_splice | Splice Site (SNP) | VAF 65/159 reads (41%) | called by muse, mutect2, varscan2
- POLA1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POM121 | c.940A>G p.S314G (on ENST00000434423; = p.S49G on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PPP1R13L | c.224T>G p.I75S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, varscan2
- PPP4R1 | c.740A>C p.Q247P (on ENST00000400556 / NM_001042388.3; = p.Q230P on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- PRDM9 | c.2448G>T p.K816N | Missense Mutation (SNP) | VAF 76/322 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.176); called by muse, varscan2
- PTCHD4 | c.1389del p.K464Sfs*32 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- PTCHD4 | c.1011G>T p.M337I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PTX3 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PYHIN1 | c.939G>T p.K313N | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIMS1 | c.529G>T p.A177S | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ROBO3 | c.2483G>T p.R828L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.9); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RPN2 | c.1436A>T p.Y479F | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RREB1 | c.4910C>A p.T1637K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RTL3 | c.461A>T p.K154M | Missense Mutation (SNP) | VAF 51/61 reads (84%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- RTTN | c.4564+1G>T p.X1522_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | called by muse, mutect2
- SCN2A | c.5112G>A p.M1704I | Missense Mutation (SNP) | VAF 132/316 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- SDF2 | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SERPINA3 | c.52T>C p.C18R | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SH2B1 | c.1375G>C p.A459P | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- SH2D4B | c.1223C>A p.T408N (on ENST00000646907; = p.H333Q on NM_207372.2) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- SHCBP1 | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLECL1 | c.24A>T p.V8= | Splice Region (SNP) | VAF 62/149 reads (42%) | called by muse, mutect2, varscan2
- SLC1A3 | c.1353G>T p.M451I | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- SLC22A11 | c.821+1G>A p.X274_splice | Splice Site (SNP) | VAF 71/189 reads (38%) | called by muse, mutect2, varscan2
- SLC28A2 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC43A3 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC45A2 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SNAP47 | c.300G>T p.E100D | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SNX7 | c.441A>T p.K147N | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SPACA1 | c.277A>G p.R93G | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- STYXL2 | c.1938G>T p.W646C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAFA2 | c.347G>T p.W116L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- TARBP1 | c.2616G>T p.L872F | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCF20 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 49/185 reads (26%) | called by muse, mutect2, varscan2
- TEP1 | c.5621G>T p.G1874V | Missense Mutation (SNP) | VAF 73/104 reads (70%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TIAM2 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM132D | c.1723G>C p.A575P | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM200A | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TMPRSS3 | c.1348-1G>A p.X450_splice | Splice Site (SNP) | VAF 36/45 reads (80%) | called by muse, mutect2, varscan2
- TNRC6A | c.1265G>T p.S422I | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TOP2A | c.4172C>T p.S1391F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TPTE | c.857-2A>G p.X286_splice (on ENST00000618007 / NM_199261.4; = p.X268_splice on NM_199259.4) | Splice Site (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
- TRIM33 | c.2348A>G p.D783G | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TRPM6 | c.856G>C p.V286L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- TRPS1 | c.2337A>T p.K779N (on ENST00000220888 / NM_001330599.2; = p.K792N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 250/571 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.44959G>A p.V14987M (on ENST00000591111; = p.V7563M on NM_003319.4) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TTN | c.21275T>C p.V7092A (on ENST00000591111; = p.V6165A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TTN | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 80/252 reads (32%) | PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- UBA2 | c.436G>T p.G146* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- UBE3C | c.596T>C p.L199S | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- UNC79 | c.3137C>A p.T1046K (on ENST00000393151 / NM_001346218.2; = p.T869K on NM_020818.5) | Missense Mutation (SNP) | VAF 46/70 reads (66%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP37 | c.2623del p.E875Nfs*2 | Frame Shift Del (DEL) | VAF 46/173 reads (27%) | called by mutect2, pindel, varscan2
- USP4 | c.2622T>A p.Y874* | Nonsense Mutation (SNP) | VAF 30/37 reads (81%) | called by muse, mutect2, varscan2
- USP46 | c.146T>A p.V49E | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- VCAM1 | c.959G>A p.G320E | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- VWCE | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WDR82 | c.620A>T p.K207M | Missense Mutation (SNP) | VAF 114/162 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- WNK4 | c.3434A>T p.H1145L | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XPO4 | c.520A>G p.S174G | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- YARS1 | c.418G>T p.V140F | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZAN | c.545G>T p.R182L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, varscan2
- ZNF197 | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 34/48 reads (71%) | called by muse, mutect2, varscan2
- ZNF236 | c.3796A>T p.R1266* | Nonsense Mutation (SNP) | VAF 40/84 reads (48%) | called by muse, mutect2, varscan2
- ZNF260 | c.809A>G p.H270R | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF417 | c.1190A>T p.Q397L | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF521 | c.2206T>A p.S736T | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF570 | c.1303G>T p.V435F | Missense Mutation (SNP) | VAF 68/164 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF700 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF780B | c.2126A>G p.H709R | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF836 | c.1820A>T p.Q607L | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ZWINT | c.587A>T p.K196M | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- AASDH | c.177G>T p.R59= | Silent (SNP) | VAF 38/103 reads (37%) | called by muse, mutect2, varscan2
- ABCA4 | c.4446C>A p.V1482= | Silent (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- ABCA4 | c.3153C>A p.L1051= | Silent (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- ACSL6 | c.1197C>A p.A399= (on ENST00000379240; = p.A424= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/93 reads (71%) | catalogued as rs375706829; called by muse, mutect2, varscan2
- ADAMTS13 | c.3657G>A p.R1219= | Silent (SNP) | VAF 66/82 reads (80%) | called by muse, mutect2, varscan2
- ADGRB2 | c.1875A>G p.L625= | Silent (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- AHNAK | c.963G>A p.E321= | Silent (SNP) | VAF 47/137 reads (34%) | called by muse, mutect2, varscan2
- AKR1D1 | c.231G>A p.V77= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1268510844; called by muse, mutect2, varscan2
- ARFGEF2 | c.2697G>A p.T899= | Silent (SNP) | VAF 55/130 reads (42%) | catalogued as rs779986717; called by muse, mutect2, varscan2
- ARNTL2 | c.1341A>G p.L447= | Silent (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- ATF6 | c.1168C>T p.L390= | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as rs1429734023, COSV63407473; called by muse, mutect2, varscan2
- ATXN7L1 | c.127C>T p.L43= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV59492715; called by muse, mutect2
- BAIAP3 | c.612C>T p.A204= | Silent (SNP) | VAF 40/92 reads (43%) | called by muse, mutect2, varscan2
- BCO1 | c.1641C>T p.T547= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- BEND3 | c.2220C>T p.A740= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs200172315, COSV64681440; called by muse, mutect2, varscan2
- BLK | c.1002C>A p.L334= | Silent (SNP) | VAF 33/45 reads (73%) | called by muse, mutect2, varscan2
- C3orf56 | c.561C>A p.P187= | Silent (SNP) | VAF 24/78 reads (31%) | called by muse, mutect2, varscan2
- CALCRL | c.1053G>T p.L351= | Silent (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- CCDC174 | c.1140A>T p.S380= | Silent (SNP) | VAF 31/36 reads (86%) | called by muse, mutect2, varscan2
- CCM2L | c.207C>T p.G69= | Silent (SNP) | VAF 17/459 reads (4%) | called by muse, mutect2
- CERS3 | c.223C>A p.R75= | Silent (SNP) | VAF 55/138 reads (40%) | catalogued as rs747911784, COSV52566853; called by muse, mutect2, varscan2
- CHTOP | c.18G>T p.A6= | Silent (SNP) | VAF 50/85 reads (59%) | catalogued as COSV52679569, COSV52680113; called by muse, mutect2, varscan2
- CNTRL | c.555A>G p.P185= | Silent (SNP) | VAF 87/101 reads (86%) | called by muse, mutect2, varscan2
- COL12A1 | c.7311C>A p.S2437= | Silent (SNP) | VAF 50/111 reads (45%) | catalogued as COSV59400696; called by muse, mutect2, varscan2
- CORO2A | c.990C>T p.L330= | Silent (SNP) | VAF 45/57 reads (79%) | catalogued as rs368276546, COSV59663016; called by muse, mutect2, varscan2
- CPLANE1 | c.7992G>A p.Q2664= | Silent (SNP) | VAF 30/127 reads (24%) | catalogued as COSV57065232; called by muse, mutect2, varscan2
- CR1L | c.1092T>C p.F364= | Silent (SNP) | VAF 127/335 reads (38%) | called by muse, mutect2, varscan2
- CRNN | c.717C>A p.T239= | Silent (SNP) | VAF 289/527 reads (55%) | catalogued as COSV55121188; called by muse, mutect2, varscan2
- DCAF4L2 | c.432G>C p.L144= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as COSV60479877; called by muse, mutect2, varscan2
- DCAF8L1 | c.1773C>A p.G591= | Silent (SNP) | VAF 42/51 reads (82%) | called by muse, mutect2, varscan2
- DGKK | c.792C>A p.A264= | Silent (SNP) | VAF 27/34 reads (79%) | called by muse, mutect2, varscan2
- DIS3 | c.2085T>G p.P695= | Silent (SNP) | VAF 62/85 reads (73%) | called by muse, mutect2, varscan2
- E2F7 | c.1458C>T p.L486= | Silent (SNP) | VAF 79/193 reads (41%) | catalogued as COSV59740031; called by muse, mutect2, varscan2
- ECPAS | c.2343A>G p.Q781= | Silent (SNP) | VAF 234/279 reads (84%) | called by muse, mutect2, varscan2
- FGFR2 | c.738G>T p.L246= | Silent (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- FPR3 | c.381C>A p.V127= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV59329289; called by muse, mutect2, varscan2
- FRMD1 | c.1476C>T p.H492= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV51964590; called by muse, mutect2, varscan2
- FUT5 | c.750G>C p.T250= | Silent (SNP) | VAF 66/94 reads (70%) | called by muse, mutect2, varscan2
- GCKR | c.252A>T p.V84= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- GRM5 | c.2670A>C p.I890= | Silent (SNP) | VAF 209/289 reads (72%) | called by muse, mutect2, varscan2
- HGD | c.1095C>T p.H365= | Silent (SNP) | VAF 77/138 reads (56%) | called by muse, mutect2, varscan2
- HPN | c.660T>A p.G220= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as rs1231714175; called by muse, mutect2, varscan2
- IGDCC3 | c.1554G>C p.L518= | Silent (SNP) | VAF 103/128 reads (80%) | catalogued as COSV100031539; called by muse, mutect2, varscan2
- IGF2BP2 | c.1176C>T p.P392= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs769463946; called by muse, mutect2, varscan2
- ITGA2B | c.1809C>T p.S603= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV52235462; called by muse, mutect2
- ITIH1 | c.1779C>A p.A593= | Silent (SNP) | VAF 39/53 reads (74%) | catalogued as COSV56257707; called by muse, mutect2, varscan2
- KCNJ11 | c.1116C>T p.S372= | Silent (SNP) | VAF 43/56 reads (77%) | catalogued as rs753294641, COSV60595506; called by muse, mutect2, varscan2
- KIAA0408 | c.546A>G p.Q182= | Silent (SNP) | VAF 52/129 reads (40%) | called by muse, mutect2, varscan2
- KIAA1210 | c.27C>T p.G9= | Silent (SNP) | VAF 64/71 reads (90%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.807G>T p.V269= | Silent (SNP) | VAF 79/238 reads (33%) | called by muse, mutect2, varscan2
- LEP | c.132C>T p.D44= | Silent (SNP) | VAF 91/229 reads (40%) | catalogued as rs372064089; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.432C>A p.L144= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs747582062; called by muse, mutect2, varscan2
- LZTS1 | c.300G>T p.P100= | Silent (SNP) | VAF 20/24 reads (83%) | called by muse, mutect2, varscan2
- MAEA | c.345G>A p.A115= | Silent (SNP) | VAF 63/182 reads (35%) | catalogued as rs370344362; called by muse, mutect2, varscan2
- MAGEE1 | c.426C>T p.P142= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as COSV63909202, COSV63911624; called by muse, mutect2, varscan2
- MATN2 | c.402C>G p.T134= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs781471020; called by muse, mutect2, varscan2
- MATN4 | c.1455C>T p.P485= (on ENST00000372754; = p.P444= on NM_003833.4) | Silent (SNP) | VAF 53/98 reads (54%) | called by muse, mutect2, varscan2
- MEIS2 | c.1326A>G p.G442= | Silent (SNP) | VAF 163/958 reads (17%) | called by muse, mutect2, varscan2
- MEP1A | c.514C>A p.R172= | Silent (SNP) | VAF 100/251 reads (40%) | called by muse, mutect2, varscan2
- METTL4 | c.1299A>G p.P433= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as rs761394381; called by muse, mutect2, varscan2
- MROH2B | c.558C>A p.I186= | Silent (SNP) | VAF 68/242 reads (28%) | called by muse, mutect2, varscan2
- MUC4 | c.2925C>A p.T975= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- MYH4 | c.5586C>A p.R1862= | Silent (SNP) | VAF 41/59 reads (69%) | called by muse, mutect2, varscan2
- MYOM1 | c.1446C>T p.I482= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1471749545; called by muse, mutect2, varscan2
- NANOS2 | c.204C>T p.H68= | Silent (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- NPHP4 | c.2946C>T p.H982= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs766172633; called by muse, mutect2, varscan2
- NYAP2 | c.1107G>T p.V369= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- OBSCN | c.10275A>C p.A3425= | Silent (SNP) | VAF 51/119 reads (43%) | called by muse, mutect2, varscan2
- OCA2 | c.108C>T p.R36= | Silent (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- OLFM1 | c.1185G>T p.T395= (on ENST00000371793 / NM_001282611.2; = p.T377= on NM_014279.5) | Silent (SNP) | VAF 49/57 reads (86%) | called by muse, mutect2, varscan2
- OR52E2 | c.126A>T p.I42= | Silent (SNP) | VAF 41/52 reads (79%) | called by muse, mutect2, varscan2
- OR5AC2 | c.669G>T p.V223= | Silent (SNP) | VAF 36/53 reads (68%) | called by muse, mutect2, varscan2
- OTUD4 | c.576A>G p.E192= (on ENST00000447906 / NM_001366057.1; = p.E127= on NM_017493.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/88 reads (75%) | catalogued as rs772938029; called by muse, mutect2, varscan2
- PADI2 | c.792C>A p.G264= | Silent (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- PAPPA2 | c.2811G>T p.L937= | Silent (SNP) | VAF 162/228 reads (71%) | called by muse, mutect2, varscan2
- PEG3 | c.3033C>A p.A1011= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV99688361; called by muse, mutect2, varscan2
- PIWIL1 | c.2583C>G p.L861= | Silent (SNP) | VAF 66/162 reads (41%) | called by muse, varscan2
- PRDM14 | c.885C>T p.T295= | Silent (SNP) | VAF 78/113 reads (69%) | called by muse, mutect2, varscan2
- PRDM9 | c.426A>T p.A142= | Silent (SNP) | VAF 52/171 reads (30%) | catalogued as COSV57009808; called by muse, mutect2, varscan2
- PXDC1 | c.456C>G p.V152= | Silent (SNP) | VAF 72/210 reads (34%) | catalogued as COSV66662089; called by muse, mutect2, varscan2
- RYR3 | c.10404G>A p.R3468= (on ENST00000389232; = p.R3469= on NM_001036.6) | Silent (SNP) | VAF 57/290 reads (20%) | called by muse, mutect2, varscan2
- SCARF1 | c.858G>T p.P286= | Silent (SNP) | VAF 8/9 reads (89%) | called by muse, mutect2, varscan2
- SLC18A2 | c.6C>A p.A2= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- SLC25A32 | c.582G>T p.S194= | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2
- SLC39A12 | c.852T>C p.H284= | Silent (SNP) | VAF 51/120 reads (43%) | called by muse, mutect2, varscan2
- SP140 | c.606C>A p.L202= | Silent (SNP) | VAF 43/84 reads (51%) | catalogued as COSV59450086; called by muse, mutect2, varscan2
- SPATA1 | c.172C>T p.L58= | Silent (SNP) | VAF 69/154 reads (45%) | called by muse, mutect2, varscan2
- STAT5A | c.270C>T p.Y90= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs570501894; called by muse, mutect2, varscan2
- SUPT5H | c.402A>G p.E134= | Silent (SNP) | VAF 54/141 reads (38%) | called by muse, mutect2, varscan2
- TAOK1 | c.558G>T p.P186= | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- TAPBPL | c.543C>G p.P181= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- TFDP1 | c.747G>T p.R249= | Silent (SNP) | VAF 51/71 reads (72%) | called by muse, mutect2, varscan2
- TMEM252 | c.321G>T p.V107= | Silent (SNP) | VAF 36/48 reads (75%) | called by muse, mutect2, varscan2
- TNFRSF8 | c.1275G>C p.P425= | Silent (SNP) | VAF 87/214 reads (41%) | catalogued as COSV99820983; called by muse, mutect2, varscan2
- TRIM50 | c.354A>G p.Q118= | Silent (SNP) | VAF 38/195 reads (19%) | catalogued as rs1554545575; called by muse, mutect2, varscan2
- TRPV1 | c.312C>T p.A104= | Silent (SNP) | VAF 34/49 reads (69%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.18C>T p.T6= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99270059; called by muse, mutect2, varscan2
- TTN | c.42819C>T p.V14273= (on ENST00000591111; = p.V6849= on NM_003319.4) | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- TTN | c.22200T>A p.S7400= (on ENST00000591111; = p.S6473= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100610515; called by muse, mutect2, varscan2
- UNC80 | c.361C>T p.L121= | Silent (SNP) | VAF 49/125 reads (39%) | called by muse, mutect2, varscan2
- XIRP2 | c.5310A>T p.I1770= (on ENST00000628543; = p.I1945= on NM_152381.6) | Silent (SNP) | VAF 28/71 reads (39%) | called by muse, mutect2, varscan2
- ZIC1 | c.159G>T p.S53= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as COSV51552051; called by muse, mutect2, varscan2
- ZNF208 | c.2775C>A p.A925= | Silent (SNP) | VAF 22/29 reads (76%) | catalogued as COSV104432331; called by muse, mutect2, varscan2
- ZNF451 | c.2136A>T p.P712= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- ZSCAN30 | c.165T>C p.S55= | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2394C>A | RNA (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73848627 A>C | 5'Flank (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- DDX50 | c.*1G>A | 3'UTR (SNP) | VAF 60/180 reads (33%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+6934A>G | Intron (SNP) | VAF 66/155 reads (43%) | called by muse, mutect2, varscan2
- H2BP2 | n.1062-314C>A | Intron (SNP) | VAF 51/141 reads (36%) | catalogued as rs1435113503; called by muse, mutect2, varscan2
- HAS3 | chr16:69118444 C>A | 3'Flank (SNP) | VAF 24/42 reads (57%) | called by muse, mutect2, varscan2
- HRH2 | chr5:175683232 G>T | 5'Flank (SNP) | VAF 95/132 reads (72%) | called by muse, mutect2, varscan2
- NCF2 | c.-1C>T | 5'UTR (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2
- PLEKHA8P1 | n.727G>T | RNA (SNP) | VAF 95/200 reads (48%) | called by muse, mutect2, varscan2
- PPP1R1A | chr12:54577458 A>T | 3'Flank (SNP) | VAF 112/293 reads (38%) | called by muse, mutect2, varscan2
- PTGER3 | c.*24-12919C>T | Intron (SNP) | VAF 32/87 reads (37%) | catalogued as rs1301398407, COSV63386812; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99791471 A>T | 3'Flank (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- RNU7-174P | chr8:80558966 C>T | 5'Flank (SNP) | VAF 22/34 reads (65%) | catalogued as rs771458757; called by muse, mutect2, varscan2
- SON | c.6657+334A>G | Intron (SNP) | VAF 75/109 reads (69%) | catalogued as rs199834480; called by muse, mutect2, varscan2
- SSPOP | n.11961G>T | RNA (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
